Somatic mutation profile of tumor specimen ALCH-B3AE-TTP1-A (aliquot ALCH-B3AE-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3AE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.1 years (27,079 days).
Specimen ALCH-B3AE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdb8955b-b39f-4204-82b2-eae2c9916dee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3AE-NB1-A (Blood Derived Normal), aliquot ALCH-B3AE-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2edae59d-d186-42f6-99d5-38666c1b5a01

The open-access MAF lists 69 somatic variants for this specimen: 59 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Nonsense Mutation 7, Silent 6, Intron 3, Splice Site 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 43/763 reads (6%) | hotspot (GDC flag); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; called by muse, mutect2
- ALK | c.1948C>T p.P650S | Missense Mutation (SNP) | VAF 48/1180 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV101202740; called by muse, mutect2
- CARD11 | c.3096C>A p.N1032K | Missense Mutation (SNP) | VAF 27/404 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV67796809; called by muse, mutect2
- CHRNB3 | c.1169del p.A390Vfs*17 | Frame Shift Del (DEL) | VAF 28/294 reads (10%) | catalogued as COSV51494663; called by mutect2, pindel
- COL25A1 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 16/497 reads (3%) | catalogued as COSV67650756; called by muse, mutect2
- DSC2 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 38/1012 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51865674; called by muse, mutect2
- FGF10 | c.285C>A p.N95K | Missense Mutation (SNP) | VAF 32/637 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.116); catalogued as COSV52933053, COSV52934519; called by muse, mutect2
- MAG | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 13/125 reads (10%) | catalogued as COSV62700123; called by muse, mutect2, varscan2
- MSN | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 21/366 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as rs1169768462, COSV100814249; called by muse, mutect2
- NEO1 | c.1579C>G p.P527A | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1319768408; called by muse, mutect2
- NTRK1 | c.2015G>A p.S672N | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as rs1558108205; ClinVar: uncertain significance; called by muse, mutect2
- OLFM3 | c.1276A>T p.T426S (on ENST00000338858 / NM_001288821.1; = p.T406S on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV58804379; called by muse, mutect2
- OR51E2 | c.525C>A p.H175Q | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV67807548; called by muse, mutect2
- PCDH15 | c.3745C>A p.Q1249K | Missense Mutation (SNP) | VAF 34/1078 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV57316565; called by muse, mutect2
- PCDH15 | c.3744G>A p.M1248I | Missense Mutation (SNP) | VAF 36/1076 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs1180775276; called by muse, mutect2
- RIMS2 | c.214G>T p.V72L | Missense Mutation (SNP) | VAF 48/751 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68471119; called by muse, mutect2
- ZNF41 | c.1709A>G p.Q570R | Missense Mutation (SNP) | VAF 22/281 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV57444470; called by muse, mutect2
- ABCA8 | c.1235A>G p.Y412C | Missense Mutation (SNP) | VAF 13/369 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- ADAM23 | c.656+2T>A p.X219_splice | Splice Site (SNP) | VAF 22/696 reads (3%) | called by muse, mutect2
- ALPK2 | c.3527C>A p.P1176H | Missense Mutation (SNP) | VAF 17/345 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); called by muse, mutect2
- ARHGEF26 | c.625A>G p.S209G | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); called by muse, mutect2
- ATP10D | c.3189G>T p.M1063I | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- C5orf22 | c.825A>C p.L275F | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CACNA1E | c.4207T>C p.Y1403H | Missense Mutation (SNP) | VAF 26/904 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CD207 | c.959A>G p.K320R | Missense Mutation (SNP) | VAF 11/197 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL25A1 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2
- DGLUCY | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 29/543 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.123); called by muse, mutect2
- GRK3 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 16/424 reads (4%) | called by muse, mutect2
- GTF3C4 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 32/834 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2
- HAUS5 | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 11/284 reads (4%) | called by muse, mutect2
- IL12B | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 31/1172 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.163); called by muse, mutect2
- KDM4E | c.1458A>C p.R486S | Missense Mutation (SNP) | VAF 23/489 reads (5%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.012); called by muse, mutect2
- KRT9 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 16/478 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LSAMP | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 11/263 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- MASP1 | c.498C>A p.C166* | Nonsense Mutation (SNP) | VAF 94/1088 reads (9%) | called by muse, mutect2
- MUC22 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.47); called by muse, mutect2
- NEDD4L | c.2144G>A p.R715K (on ENST00000400345 / NM_001144967.3; = p.R695K on NM_015277.6) | Missense Mutation (SNP) | VAF 26/626 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- NRAP | c.1804C>T p.L602F (on ENST00000359988 / NM_001322945.2; = p.L567F on NM_006175.4) | Missense Mutation (SNP) | VAF 26/570 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); called by muse, mutect2
- NUP35 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 12/376 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- PKHD1L1 | c.8116A>T p.N2706Y | Missense Mutation (SNP) | VAF 30/808 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- PLCE1 | c.1914G>T p.M638I | Missense Mutation (SNP) | VAF 26/886 reads (3%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.63); called by muse, mutect2
- PLEKHM2 | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLXNA3 | c.293A>T p.K98M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PNLIPRP3 | c.1028T>C p.F343S | Missense Mutation (SNP) | VAF 18/299 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- POTEI | c.323G>C p.C108S | Missense Mutation (SNP) | VAF 21/738 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- PRDM9 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 32/1024 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PRDM9 | c.959A>T p.N320I | Missense Mutation (SNP) | VAF 45/1136 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- PRDM9 | c.960C>A p.N320K | Missense Mutation (SNP) | VAF 46/1142 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2
- PTPRD | c.2002G>T p.D668Y | Missense Mutation (SNP) | VAF 34/1120 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2
- SATL1 | c.140G>T p.S47I (on ENST00000395409; = p.S234I on NM_001012980.2) | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.781); called by muse, mutect2
- SLC8A3 | c.696G>A p.W232* | Nonsense Mutation (SNP) | VAF 10/223 reads (4%) | called by muse, mutect2
- SPC25 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 22/740 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TLN2 | c.3880G>T p.A1294S | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2
- TLR9 | c.1840T>C p.W614R | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM55 | c.1271C>A p.T424K | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.115); called by muse, mutect2
- TTN | c.17240A>T p.D5747V (on ENST00000591111; = p.D4820V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/560 reads (4%) | PolyPhen possibly damaging (0.448); called by muse, mutect2
- TUBB8B | c.1019A>G p.Y340C | Missense Mutation (SNP) | VAF 22/674 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.25); called by muse, mutect2
- ZNF775 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.325); called by muse, mutect2
- ZSCAN18 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- ABCC1 | c.3336G>A p.T1112= | Silent (SNP) | VAF 8/151 reads (5%) | catalogued as rs767072123, COSV60686836; called by muse, mutect2
- ALMS1 | c.10119C>T p.L3373= | Silent (SNP) | VAF 28/928 reads (3%) | called by muse, mutect2
- C1S | c.90G>A p.Q30= | Silent (SNP) | VAF 21/786 reads (3%) | called by muse, mutect2
- DMXL1 | c.3981C>G p.P1327= | Silent (SNP) | VAF 24/904 reads (3%) | catalogued as COSV100224575; called by muse, mutect2
- OR11G2 | c.708C>A p.V236= | Silent (SNP) | VAF 18/500 reads (4%) | catalogued as COSV100639997, COSV62133177; called by muse, mutect2
- PIK3AP1 | c.1500G>A p.E500= | Silent (SNP) | VAF 26/528 reads (5%) | called by muse, mutect2
- ADGRB3 | c.2481-661G>T | Intron (SNP) | VAF 13/323 reads (4%) | called by muse, mutect2
- AL353804.6 | chrX:73827192 G>T | 3'Flank (SNP) | VAF 14/282 reads (5%) | called by muse, mutect2
- KALRN | c.7194-617A>G | Intron (SNP) | VAF 23/355 reads (6%) | catalogued as COSV52261765; called by muse, mutect2
- USE1 | c.394+136G>A | Intron (SNP) | VAF 18/468 reads (4%) | called by muse, mutect2
